Gene-level copy-number profile of specimen HCM-SANG-1328-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-1328-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-1328-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 810696dd-157c-4394-be8e-410b65b46111.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1328-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/bdf0fd34-01ea-4d56-a1d9-fdb0d513d07d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 443; copy number 1: 2,570; copy number 2: 24,972; copy number 3: 25,498; copy number 4: 3,355; copy number 5: 1,404; copy number 6: 163; copy number 7: 362; copy number 8: 13; copy number 9: 88; copy number 10: 10; copy number 15: 9; copy number 25: 19.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:3,824,127–4,708,399, 12 genes: GLIS3, AL137071.1, GLIS3-AS1, AL359095.1, AL162419.1, RNU6-694P, SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT, CDC37L1.
- chr9:41,340,823–41,648,035, 8 genes: CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5.
- chr9:64,621,560–64,652,556, 2 genes: AQP7P2, AL445665.1.
- chr18:79,253,577–79,254,856, 1 gene (within-gene range 0–1): AC104423.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 501 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:55,282,319–55,435,622, 5 genes, copy number 7: PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5.
- chr2:85,685,175–85,905,199, 10 genes, copy number 7–8: GNLY, GPR160P1, RNU1-38P, ATOH8, MIR6071, AC105053.1, RN7SKP83, ST3GAL5, ST3GAL5-AS1, AC012511.1.
- chr6:29,790,954–30,830,659, 83 genes, copy number 7 (broad region; genes not listed).
- chr6:31,765,590–32,473,500, 61 genes, copy number 7–8 (broad region; genes not listed).
- chr12:24,212,421–25,648,579, 30 genes, copy number 8–25: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1.
- chr17:61,865,367–67,744,531, 178 genes, copy number 7–10 (broad region; genes not listed).
- chr17:68,259,182–68,422,731, 1 gene, copy number 7 (within-gene range 5–7): ARSG.
- chr17:68,413,623–75,182,959, 133 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,570. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
